Somatic mutation profile of tumor specimen TCGA-TM-A7CA-01A (aliquot TCGA-TM-A7CA-01A-21D-A33T-08) from TCGA case TCGA-TM-A7CA, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 44.9 years (16,415 days).
Specimen TCGA-TM-A7CA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4a3c98f4-e7f2-48fc-923d-ccef7e2e5083.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-TM-A7CA-10A (Blood Derived Normal), aliquot TCGA-TM-A7CA-10A-01D-A33W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/df6173da-c996-4cea-b46b-eb5470cf517e

The open-access MAF lists 39 somatic variants for this specimen: 31 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 21, Silent 8, Frame Shift Del 4, Nonsense Mutation 3, Frame Shift Ins 1, In Frame Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 52/150 reads (35%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.1024C>T p.R342* | Nonsense Mutation (SNP) | VAF 25/60 reads (42%) | hotspot (GDC flag); catalogued as rs730882029, CM004908, COSV52665487; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.267del p.S90Pfs*33 | Frame Shift Del (DEL) | VAF 59/162 reads (36%) | catalogued as rs587783062; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- ALDOA | c.1064_1066del p.S355del (on ENST00000642816 / NM_001243177.4; = p.S301del on NM_184041.5) | In Frame Del (DEL) | VAF 9/74 reads (12%) | catalogued as rs760550827; called by mutect2, pindel, varscan2
- ARID1A | c.3977dup p.Q1327Afs*11 | Frame Shift Ins (INS) | VAF 46/178 reads (26%) | catalogued as COSV61376881; called by pindel, varscan2
- BTBD16 | c.1471G>A p.V491M | Missense Mutation (SNP) | VAF 7/146 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.944); catalogued as COSV99584594; called by muse, mutect2
- CRB2 | c.2182C>G p.L728V | Missense Mutation (SNP) | VAF 14/236 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV100749569; called by muse, mutect2
- DLL3 | c.13C>G p.R5G | Missense Mutation (SNP) | VAF 9/205 reads (4%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.011); catalogued as COSV52695602, COSV99218900; called by muse, mutect2
- GREB1 | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 10/204 reads (5%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.879); catalogued as COSV99302440; called by muse, mutect2
- MACROD1 | c.337C>A p.H113N | Missense Mutation (SNP) | VAF 70/232 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.517); catalogued as COSV99734854; called by muse, mutect2, varscan2
- MVB12A | c.190-2A>G p.X64_splice | Splice Site (SNP) | VAF 19/57 reads (33%) | catalogued as COSV100396459; called by muse, mutect2, varscan2
- NR2F2 | c.234G>C p.E78D | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.59); PolyPhen benign (0.039); catalogued as rs753715153, COSV101240967; called by muse, mutect2, varscan2
- OR5M8 | c.489C>A p.Y163* | Nonsense Mutation (SNP) | VAF 10/163 reads (6%) | catalogued as COSV100510582; called by muse, mutect2
- PIWIL4 | c.1180C>T p.Q394* | Nonsense Mutation (SNP) | VAF 10/216 reads (5%) | catalogued as COSV100133141; called by muse, mutect2
- POPDC3 | c.821G>A p.R274H | Missense Mutation (SNP) | VAF 94/230 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as rs769396346, COSV99633513; called by muse, mutect2, varscan2
- PROKR2 | c.1058G>A p.R353H | Missense Mutation (SNP) | VAF 41/151 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.317); catalogued as rs576243101, COSV54085395; called by muse, mutect2, varscan2
- RET | c.2419G>A p.A807T | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs760012685, COSV100392822, COSV60703267; called by muse, mutect2, varscan2
- RPS6KB1 | c.239A>G p.N80S | Missense Mutation (SNP) | VAF 109/338 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV99847400; called by muse, mutect2, varscan2
- RTP4 | c.398A>T p.K133M | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.94); catalogued as COSV99372250; called by muse, mutect2, varscan2
- RYK | c.869A>G p.N290S | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.561); catalogued as COSV99938323; called by muse, mutect2, varscan2
- RYR2 | c.1030A>G p.K344E | Missense Mutation (SNP) | VAF 76/175 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.047); catalogued as COSV100768873; called by muse, mutect2, varscan2
- SLC4A8 | c.2302C>T p.R768C | Missense Mutation (SNP) | VAF 92/265 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs868263140, COSV60656599; called by muse, mutect2, varscan2
- SMC3 | c.2772G>C p.K924N | Missense Mutation (SNP) | VAF 15/226 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100699840; called by muse, mutect2
- SPTA1 | c.4048G>C p.D1350H | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.796); catalogued as COSV100934600; called by muse, mutect2
- STAM | c.263A>G p.D88G | Missense Mutation (SNP) | VAF 52/181 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as COSV101092208; called by muse, mutect2, varscan2
- TRIM58 | c.980A>G p.E327G | Missense Mutation (SNP) | VAF 5/86 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.757); catalogued as COSV100824950; called by muse, mutect2
- USH2A | c.9881G>C p.C3294S | Missense Mutation (SNP) | VAF 14/146 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV100231323; called by muse, mutect2
- USP7 | c.2788G>A p.E930K | Missense Mutation (SNP) | VAF 27/563 reads (5%) | SIFT tolerated (0.3); PolyPhen benign (0.049); catalogued as rs982273663, COSV100784059, COSV100784384; called by muse, mutect2
- ARID2 | c.167_171del p.T56Rfs*8 | Frame Shift Del (DEL) | VAF 40/124 reads (32%) | called by mutect2, pindel, varscan2
- ATRX | c.4736_4737del p.V1579Efs*21 | Frame Shift Del (DEL) | VAF 130/228 reads (57%) | called by pindel, varscan2
- TMC6 | c.2347_2351del p.R783Qfs*18 | Frame Shift Del (DEL) | VAF 37/112 reads (33%) | called by pindel, varscan2
- ATP10D | c.222T>C p.N74= | Silent (SNP) | VAF 79/169 reads (47%) | catalogued as rs202206103, COSV99905337; called by muse, mutect2, varscan2
- CUBN | c.2679A>G p.T893= | Silent (SNP) | VAF 92/389 reads (24%) | catalogued as COSV100912278; called by muse, mutect2, varscan2
- MIA2 | c.549C>G p.L183= | Silent (SNP) | VAF 18/306 reads (6%) | catalogued as rs199571113, COSV99697423; called by muse, mutect2
- PCDH7 | c.2661G>T p.L887= | Silent (SNP) | VAF 10/224 reads (4%) | called by muse, mutect2
- PDE8B | c.2202A>G p.E734= | Silent (SNP) | VAF 48/168 reads (29%) | catalogued as COSV99366383; called by muse, mutect2, varscan2
- PPP1R3A | c.1444T>C p.L482= | Silent (SNP) | VAF 12/246 reads (5%) | catalogued as COSV99492282; called by muse, mutect2
- SIGMAR1 | c.495G>A p.G165= | Silent (SNP) | VAF 51/109 reads (47%) | catalogued as COSV99449474; called by muse, mutect2, varscan2
- YAP1 | c.876A>G p.G292= (on ENST00000282441 / NM_001130145.3; = p.G254= on NM_006106.5) | Silent (SNP) | VAF 6/128 reads (5%) | catalogued as COSV99176058; called by muse, mutect2
